Somatic mutation profile of tumor specimen TCGA-DD-A73G-01A (aliquot TCGA-DD-A73G-01A-22D-A32G-10) from TCGA case TCGA-DD-A73G, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.8 years (26,949 days).
Specimen TCGA-DD-A73G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ec3b8d6-22a1-4574-aab7-177fe7ea2acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73G-10A (Blood Derived Normal), aliquot TCGA-DD-A73G-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b482df7e-a280-4154-a3e1-49bdc3816de8

The open-access MAF lists 126 somatic variants for this specimen: 91 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 34, Nonsense Mutation 7, Frame Shift Ins 3, In Frame Del 2, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG7 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV56295053; called by muse, mutect2, varscan2
- AP3B2 | c.3095G>A p.C1032Y (on ENST00000261722; = p.C1026Y on NM_004644.5) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV55608031; called by muse, mutect2, varscan2
- ARL5B | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66011063; called by muse, mutect2, varscan2
- BAP1 | c.507C>G p.H169Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56232335; called by muse, mutect2, varscan2
- BIN1 | c.1686G>A p.W562* (on ENST00000316724 / NM_001320642.1; = p.W423* on NM_004305.4) | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV52117101; called by muse, mutect2, varscan2
- C5 | c.2452A>T p.K818* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV56325657; called by muse, mutect2, varscan2
- CD109 | c.2858C>G p.A953G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV54647455; called by muse, mutect2, varscan2
- CHAC1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781632634, COSV71436009; called by muse, mutect2, varscan2
- CPNE3 | c.486C>A p.Y162* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV52205235; called by muse, mutect2, varscan2
- CPNE6 | c.1125C>G p.D375E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV53743285; called by muse, mutect2, varscan2
- CPSF4 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52856952; called by muse, mutect2, varscan2
- CRYBA4 | c.444-1G>A p.X148_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as rs751386235, COSV61321479; called by muse, mutect2, varscan2
- CYP2C9 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV53247604; called by muse, mutect2, varscan2
- DSPP | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.047); catalogued as COSV56809140; called by muse, mutect2, varscan2
- EFCAB7 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 78/467 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371640057; called by muse, mutect2, varscan2
- EIF4G2 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV60596643; called by muse, mutect2
- EMILIN3 | c.1818C>A p.S606R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60035614; called by muse, mutect2
- EML2 | c.452A>C p.H151P | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55598444, COSV55603835; called by muse, mutect2, varscan2
- ESRP2 | c.936C>A p.D312E (on ENST00000565858 / NM_001365264.1; = p.D302E on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV52172757; called by muse, mutect2, varscan2
- EVX2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV57962847; called by muse, mutect2, varscan2
- FANCA | c.2605C>G p.Q869E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59796095; called by mutect2, varscan2
- FBLIM1 | c.612C>G p.Y204* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60029148; called by muse, mutect2, varscan2
- FER1L5 | c.6227G>T p.G2076V (on ENST00000623019; = p.G2040V on NM_001293083.2) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV53841042; called by muse, mutect2, varscan2
- FYCO1 | c.3076A>G p.K1026E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56114890; called by muse, mutect2, varscan2
- GLOD5 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV57488973; called by muse, mutect2
- GPR101 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs143030995, COSV53238063; called by muse, mutect2, varscan2
- GTF3C2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53125713; called by muse, mutect2, varscan2
- HEATR5A | c.2429A>G p.Q810R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV66339392; called by muse, mutect2, varscan2
- IFT140 | c.2689C>A p.R897S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV54152152, COSV54152935; called by muse, mutect2, varscan2
- IWS1 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV54867191; called by muse, mutect2, varscan2
- KCNK15 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754418071, COSV65719453; called by muse, mutect2, varscan2
- KCNK16 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64677672; called by muse, mutect2, varscan2
- KIRREL2 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52875147; called by muse, mutect2, varscan2
- KMT2C | c.12356C>T p.P4119L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs745808781, COSV51423312, COSV51481745; called by muse, mutect2, varscan2
- LRP1 | c.5179G>A p.A1727T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV54506064; called by muse, mutect2, varscan2
- LRRC28 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV57336885; called by muse, mutect2, varscan2
- MAGEA11 | c.1250T>A p.L417Q | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as COSV60754625; called by muse, mutect2, varscan2
- MCM3AP | c.4405A>T p.M1469L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52438098; called by muse, mutect2, varscan2
- MSANTD4 | c.18A>T p.R6S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57285457; called by muse, mutect2, varscan2
- MYBPC3 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV57025246; called by muse, mutect2, varscan2
- MYH11 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55547756; called by muse, mutect2, varscan2
- NXPE3 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762578763, COSV56289177; called by muse, mutect2, varscan2
- OAS2 | c.1490C>A p.T497K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.673); catalogued as COSV60801794; called by muse, mutect2, varscan2
- OR10K2 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59220759; called by muse, mutect2, varscan2
- OR1J2 | c.873C>G p.S291R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV58944064; called by muse, mutect2, varscan2
- PAPOLA | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs748090763, COSV53480139; called by muse, mutect2, varscan2
- PARM1 | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56651729; called by muse, mutect2, varscan2
- PCDHA8 | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV65335631; called by muse, mutect2
- PGGHG | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV67140556; called by muse, mutect2, varscan2
- PI4KA | c.5750A>G p.Y1917C | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55407700; called by muse, mutect2, varscan2
- PLEKHG3 | c.2233C>G p.P745A (on ENST00000394691; = p.P801A on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99907259; called by muse, mutect2, varscan2
- PLEKHG3 | c.2234C>T p.P745L (on ENST00000394691; = p.P801L on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV99907261; called by muse, mutect2, varscan2
- PLVAP | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs771476239, COSV53084155; called by muse, mutect2, varscan2
- POF1B | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV53132247; called by muse, mutect2, varscan2
- PTTG2 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.294); catalogued as COSV54716422; called by muse, mutect2, varscan2
- REEP2 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54734805; called by muse, mutect2, varscan2
- RNGTT | c.1152A>G p.I384M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55648287; called by muse, mutect2, varscan2
- RYK | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as COSV56061488; called by muse, mutect2, varscan2
- SBF1 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.322); catalogued as COSV62366644; called by muse, mutect2, varscan2
- SCRN2 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51635328; called by muse, mutect2, varscan2
- SIPA1L2 | c.2114A>T p.D705V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53387295; called by muse, mutect2, varscan2
- SLC39A8 | c.766T>A p.C256S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV63222270; called by muse, mutect2, varscan2
- SOX11 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV58984114, COSV58986802; called by muse, mutect2, varscan2
- SPRR3 | c.98T>G p.F33C | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.277); catalogued as COSV54879115; called by muse, mutect2, varscan2
- ST8SIA2 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | PolyPhen probably damaging (0.999); catalogued as COSV51568206; called by muse, mutect2, varscan2
- STAT4 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV61828902; called by muse, mutect2, varscan2
- STXBP5L | c.1376C>G p.T459R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764116141, COSV56507365; called by muse, mutect2, varscan2
- TACR2 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV64822014; called by muse, mutect2, varscan2
- TASOR2 | c.516C>G p.D172E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV60166592; called by muse, mutect2
- TCF7 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs757866191, COSV58656107; called by muse, mutect2, varscan2
- TEX15 | c.3785C>T p.A1262V (on ENST00000256246; = p.A1645V on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs115550830, COSV56343986; called by muse, mutect2, varscan2
- TLR8 | c.583G>A p.G195R (on ENST00000218032 / NM_138636.5; = p.G213R on NM_016610.4) | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54317081; called by muse, mutect2, varscan2
- TRPV3 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as rs765435661, COSV56790065; called by muse, mutect2
- TTN | c.74755A>G p.K24919E (on ENST00000591111; = p.K17495E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0.352); catalogued as rs994825543, COSV59962040; ClinVar: likely benign; called by muse, mutect2, varscan2
- TYW1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs531919446; called by muse, mutect2, varscan2
- UNC45A | c.137A>C p.Q46P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs34963697; called by muse, mutect2, varscan2
- USH2A | c.4351G>T p.G1451C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1341078203, COSV56348655; called by muse, mutect2, varscan2
- WDR20 | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV54471380; called by muse, mutect2, varscan2
- WDR37 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54126532, COSV54127855; called by muse, mutect2, varscan2
- ZC3H7A | c.2666A>C p.E889A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63269018; called by muse, mutect2, varscan2
- ZFC3H1 | c.3908G>A p.S1303N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.939); catalogued as COSV66431291; called by mutect2, varscan2
- ZFP64 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs757850701, COSV53797631; called by muse, mutect2
- ZNF236 | c.2683C>G p.Q895E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53485094; called by muse, mutect2
- ZNF385B | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416542; called by muse, mutect2, varscan2
- ZNF385B | c.1293C>G p.F431L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV61176512; called by muse, mutect2, varscan2
- CDH9 | c.2313del p.P772Lfs*23 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- DUOX2 | c.1562_1564del p.N521del | In Frame Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- PTPRO | c.1163_1171del p.L388_E390del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- RPS23 | c.162dup p.V55Sfs*4 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- USP24 | c.6839_6840insT p.C2281Lfs*18 | Frame Shift Ins (INS) | VAF 141/335 reads (42%) | called by mutect2, pindel, varscan2
- ZHX1 | c.2002dup p.T668Nfs*3 | Frame Shift Ins (INS) | VAF 20/155 reads (13%) | called by mutect2, varscan2
- ABCF1 | c.2131C>T p.L711= (on ENST00000326195 / NM_001025091.2; = p.L673= on NM_001090.3) | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV58228520; called by muse, mutect2, varscan2
- ADAMTS20 | c.2202T>C p.Y734= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs370946000; called by muse, mutect2, varscan2
- C4BPA | c.390A>G p.L130= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV65536080; called by muse, mutect2, varscan2
- CALY | c.255C>A p.T85= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV53310312; called by muse, mutect2, varscan2
- DACH1 | c.2208C>T p.G736= (on ENST00000619232 / NM_001366712.1; = p.G482= on NM_004392.6) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1466581914, COSV57494320; called by muse, mutect2, varscan2
- DNAH5 | c.4086G>A p.Q1362= | Silent (SNP) | VAF 31/246 reads (13%) | catalogued as COSV54214264, COSV99450891; called by muse, mutect2, varscan2
- DNM3 | c.2235C>T p.I745= (on ENST00000355305 / NM_001350206.2; = p.I739= on NM_015569.5) | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs1204818504, COSV62455472; called by muse, mutect2
- DST | c.20724C>T p.A6908= (on ENST00000361203 / NM_001374722.1; = p.A4605= on NM_015548.5) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV55005532; called by muse, mutect2, varscan2
- FRMPD3 | c.2254C>A p.R752= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99346555, COSV99347309; called by muse, mutect2, varscan2
- IGHV3-33 | c.267C>A p.I89= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- IL25 | c.141C>T p.T47= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1566497043, COSV59305327; called by muse, varscan2
- IL33 | c.72C>T p.A24= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs557833104, COSV67342947; called by muse, mutect2, varscan2
- ITPKB | c.2265G>A p.E755= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV55259227; called by muse, mutect2, varscan2
- IZUMO4 | c.33G>C p.T11= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100642754, COSV100643115, COSV61433378; called by muse, mutect2
- MS4A3 | c.633C>T p.P211= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV53935521; called by muse, mutect2, varscan2
- OR1N2 | c.291T>C p.Y97= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65460460; called by muse, mutect2, varscan2
- PHRF1 | c.1516C>T p.L506= (on ENST00000264555 / NM_001286581.2; = p.L505= on NM_020901.4) | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV52753356; called by muse, mutect2, varscan2
- PIK3C2A | c.114T>C p.A38= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV56401497; called by muse, mutect2, varscan2
- POTEE | c.243C>A p.G81= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV58227524; called by muse, mutect2, varscan2
- PUM2 | c.2782C>T p.L928= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV57579192; called by muse, mutect2, varscan2
- SCN10A | c.5640C>A p.P1880= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV71860842; called by mutect2, varscan2
- SLC11A1 | c.942C>T p.T314= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs770089691, COSV51916336; called by muse, mutect2, varscan2
- SMYD3 | c.1041C>T p.A347= (on ENST00000490107 / NM_001375962.1; = p.A288= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1213675363, COSV63626250; called by muse, mutect2, varscan2
- SOGA1 | c.3222G>A p.Q1074= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52914684; called by muse, mutect2, varscan2
- TENM1 | c.2637G>A p.V879= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV64428458; called by muse, mutect2, varscan2
- TMPRSS9 | c.471C>T p.I157= (on ENST00000648592; = p.I123= on NM_182973.2) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV60226622; called by muse, mutect2
- TRPM7 | c.3765G>A p.S1255= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs765622293, COSV57915065; called by muse, mutect2, varscan2
- TTN | c.90186C>T p.V30062= (on ENST00000591111; = p.V22638= on NM_003319.4) | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV59962014; called by muse, mutect2, varscan2
- UNG | c.15G>A p.K5= | Silent (SNP) | VAF 42/206 reads (20%) | catalogued as COSV54356912; called by muse, mutect2, varscan2
- USP31 | c.3633C>T p.I1211= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99566077; called by muse, mutect2
- UTRN | c.7099C>A p.R2367= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV62331424; called by muse, mutect2, varscan2
- WWC3 | c.1509C>T p.A503= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV66502236; called by muse, mutect2, varscan2
- ZFYVE16 | c.1821T>C p.N607= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV62015149; called by muse, mutect2, varscan2
- ZNF280A | c.87T>C p.D29= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV57479978, COSV57482637; called by muse, mutect2, varscan2
- CAPS2 | c.1670-2681G>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100158425; called by muse, mutect2, varscan2
